Somatic mutation profile of tumor specimen TARGET-10-PATBNT-09A (aliquot TARGET-10-PATBNT-09A-01D) from TARGET case TARGET-10-PATBNT, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.5 years (4,938 days).
Specimen TARGET-10-PATBNT-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ab4bc44-38f8-44c6-8bd3-e0d1a21cb36f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATBNT-10A (Blood Derived Normal), aliquot TARGET-10-PATBNT-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28274d82-9a1c-4574-98e1-8da07066baf2

The open-access MAF lists 41 somatic variants for this specimen: 20 protein-altering or splice-affecting, 8 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 8, Intron 6, Nonsense Mutation 3, 3'UTR 2, 5'UTR 2, RNA 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 14/68 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA7 | c.2576C>T p.P859L | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV54024034; called by muse, mutect2, varscan2
- CMA1 | c.431G>T p.C144F | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1164135574, COSV51624889; called by muse, mutect2, varscan2
- DDX3X | c.1192G>T p.E398* (on ENST00000399959; = p.E399* on NM_001356.5) | Nonsense Mutation (SNP) | VAF 3/37 reads (8%) | catalogued as COSV67863355; called by muse, mutect2
- DYSF | c.2277G>T p.K759N | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV50267787; called by muse, mutect2, varscan2
- FAM131B | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs759366087, COSV58367322, COSV58375458; called by muse, mutect2, varscan2
- FNDC3B | c.973C>T p.R325* | Nonsense Mutation (SNP) | VAF 27/121 reads (22%) | catalogued as COSV61037308, COSV61041242; called by muse, mutect2, varscan2
- GUCY2D | c.2108C>T p.A703V | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.234); catalogued as rs577880164, COSV54694412; called by muse, mutect2
- HOXD3 | c.132C>A p.S44R | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs771469636, COSV50879058; called by mutect2, varscan2
- INSRR | c.3355C>T p.R1119C | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777419942, COSV100947801, COSV63870879; called by muse, mutect2, varscan2
- KCND3 | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV56174919; called by muse, mutect2, varscan2
- MAN1C1 | c.1319G>A p.R440Q | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.7); catalogued as rs1458744212, COSV104381513; called by muse, mutect2
- MYH13 | c.5749G>A p.A1917T | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs371179959; called by muse, mutect2, varscan2
- NECTIN1 | c.595C>T p.R199W | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs372177799; called by muse, mutect2
- PCDHGA3 | c.1344C>A p.N448K | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53898141; called by muse, mutect2, varscan2
- PDE6B | c.223G>A p.V75M | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.147); catalogued as rs376238566, COSV99727630; called by muse, mutect2, varscan2
- RGS3 | c.1567G>A p.G523R (on ENST00000350696 / NM_001282923.2; = p.G411R on NM_017790.4) | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs1305244481, COSV58276944, COSV58279473; called by muse, mutect2
- SHKBP1 | c.1075A>T p.K359* | Nonsense Mutation (SNP) | VAF 35/177 reads (20%) | catalogued as COSV52537572; called by muse, mutect2, varscan2
- ZNF804B | c.1277G>A p.R426K | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV60816125; called by muse, mutect2, varscan2
- MESP2 | c.637G>T p.A213S | Missense Mutation (SNP) | VAF 2/10 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2
- ACSS3 | c.1437C>T p.V479= | Silent (SNP) | VAF 6/136 reads (4%) | catalogued as COSV99699582; called by muse, mutect2
- DARS1 | c.402C>T p.D134= | Silent (SNP) | VAF 50/232 reads (22%) | catalogued as rs1389360780, COSV51539247; called by muse, mutect2, varscan2
- DDX52 | c.27G>T p.R9= | Silent (SNP) | VAF 10/130 reads (8%) | called by muse, mutect2
- ERN1 | c.2739G>A p.E913= | Silent (SNP) | VAF 31/74 reads (42%) | called by muse, mutect2, varscan2
- GPRC5B | c.1182G>A p.P394= | Silent (SNP) | VAF 47/188 reads (25%) | catalogued as rs766068160, COSV56029216; called by muse, mutect2, varscan2
- HELZ2 | c.4908C>T p.R1636= (on ENST00000467148 / NM_001037335.2; = p.R1067= on NM_033405.3) | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs367779645; called by muse, varscan2
- SYN3 | c.1131T>C p.H377= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as rs755970849; called by muse, mutect2, varscan2
- UXT | c.393C>A p.I131= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs1396335758; called by muse, mutect2, varscan2
- ADAM20P1 | n.867A>G | RNA (SNP) | VAF 23/124 reads (19%) | catalogued as rs1391070498; called by muse, mutect2, varscan2
- ARHGEF25 | chr12:57619586 T>C | 3'Flank (SNP) | VAF 45/100 reads (45%) | called by muse, mutect2, varscan2
- ATOH8 | c.960+8465G>A | Intron (SNP) | VAF 32/64 reads (50%) | catalogued as rs773801116; called by muse, mutect2, varscan2
- CEP104 | c.*70G>T | 3'UTR (SNP) | VAF 5/96 reads (5%) | called by muse, mutect2
- CFAP46 | c.3219+67C>T | Intron (SNP) | VAF 14/45 reads (31%) | catalogued as rs969242269; called by muse, mutect2, varscan2
- CPEB4 | c.-96C>A | 5'UTR (SNP) | VAF 6/25 reads (24%) | called by muse, varscan2
- CTSA | c.778-81C>A | Intron (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- CYP2W1 | c.646-34G>A | Intron (SNP) | VAF 9/26 reads (35%) | catalogued as rs778738141; called by muse, varscan2
- HS6ST3 | c.707+335697C>T | Intron (SNP) | VAF 14/62 reads (23%) | called by mutect2, varscan2
- MINAR2 | c.-40C>T | 5'UTR (SNP) | VAF 11/50 reads (22%) | called by muse, mutect2, varscan2
- RNF217-AS1 | n.2398C>T | RNA (SNP) | VAF 22/59 reads (37%) | called by muse, mutect2, varscan2
- VAMP4 | c.*34G>T | 3'UTR (SNP) | VAF 14/77 reads (18%) | catalogued as COSV99358762; called by muse, mutect2, varscan2
- WASHC4 | c.2179+62G>T | Intron (SNP) | VAF 11/53 reads (21%) | called by muse, mutect2, varscan2
